Somatic mutation profile of tumor specimen C3L-05907-54 (aliquot CPT0303920002) from CPTAC case C3L-05907, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 46.9 years (17,119 days).
Specimen C3L-05907-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 909af171-110c-4689-8cb8-990b169686ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05907-51 (Buccal Cell Normal), aliquot CPT0303960003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2447c215-7663-4635-b47e-ddddc51d67cc

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, 3'UTR 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 72/209 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNMT3A | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262825; called by muse, mutect2, varscan2
- MYH1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 132/359 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762400651; called by muse, mutect2, varscan2
- RECQL4 | c.3113G>A p.R1038H | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs374254271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUNX1 | c.755G>A p.W252* (on ENST00000344691 / NM_001001890.3; = p.W279* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 122/309 reads (39%) | catalogued as CM161062; called by muse, mutect2, varscan2
- SMC1A | c.3146G>C p.R1049P | Missense Mutation (SNP) | VAF 127/146 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM096586; called by muse, mutect2, varscan2
- UGT1A9 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 56/186 reads (30%) | catalogued as rs772152340, COSV60836173, COSV60838942; called by muse, varscan2
- VWA7 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs140707731; called by muse, mutect2, varscan2
- XKR7 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374398061; called by muse, mutect2, varscan2
- ZFP36L2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.341); catalogued as rs1455410451; called by muse, mutect2, varscan2
- ASXL2 | c.1884dup p.M629Hfs*20 | Frame Shift Ins (INS) | VAF 40/132 reads (30%) | called by mutect2, pindel
- ATP8B4 | c.1148T>C p.L383P | Missense Mutation (SNP) | VAF 163/394 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFE2 | c.910_911insCCC p.E304delinsAQ | In Frame Ins (INS) | VAF 110/302 reads (36%) | called by mutect2, pindel, varscan2
- SBSPON | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- VN1R5 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CELSR3 | c.6825C>T p.D2275= | Silent (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- NTRK2 | c.219C>T p.I73= | Silent (SNP) | VAF 109/275 reads (40%) | catalogued as rs752011080, COSV52879210; called by muse, mutect2, varscan2
- ROCK1 | c.3492A>G p.P1164= | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- ASTN2 | c.3782+3056T>A | Intron (SNP) | VAF 50/168 reads (30%) | called by muse, mutect2, varscan2
- ASTN2 | c.3782+3055C>T | Intron (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- FRG1BP | n.378A>G | RNA (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- RINT1 | c.*206A>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
